Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K8-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: (R) Kidney NOS C649
JW 6/13/14

Papillary Renal Cell Carcinoma, Type I, with infiltration of the peri-renal fat layer. Maximum dimension: 7.5 cm. Surgical margins, vasculature and Ureter are free of tumor.

Stage: pT3a, pNX, L0, V0, R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (R)

Source: NCI Genomic Data Commons file 456c5303-6a53-4ab3-96aa-56ec9bab2c1f (TCGA-5P-A9K8.66636026-A914-4E12-85D8-AAF98739E120.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).